Somatic mutation profile of tumor specimen 0DSWZ5 from CCDI case PBCHSK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Atypical choroid plexus papilloma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.5 years (186 days).
Specimen 0DSWZ5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4ce9b8e-c809-4a01-a5de-c6f8bfc9db4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSWYY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c5a945f-dde2-466a-9c2e-9f76198d752e

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC154 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 54/250 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756712895; called by muse, mutect2, varscan2
- BACH2 | c.1238G>A p.G413E | Missense Mutation (SNP) | VAF 52/515 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- PTPRD | c.3506T>A p.L1169Q | Missense Mutation (SNP) | VAF 62/1094 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.19); called by muse, mutect2
- MED23 | c.2779-34G>T | Intron (SNP) | VAF 15/492 reads (3%) | called by muse, mutect2
